Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A7VB, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A7VB-01A (Primary Tumor).

[page 1 of 6]
Referring Physician:

DOB: Age: Gender: F

Ref#: Hosp#: Provider Group :

Date of Service: Date Received:

Case #:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - F. RIGHT BREAST AND AXILLARY LYMPH NODES, MASTECTOMY, SENTINEL LYMPH NODE BIOPSIES, AND AXILLARY LYMPH NODE DISSECTION:

- Multifocal invasive ductal carcinoma, Nottingham grades 2-3. See comment.
- Largest tumor nodule: 1.5 cm in diameter (6 o'clock aspect).
- Two smaller nodules: 0.6 and 0.8 cm (7-8 o'clock aspect).
- Ductal carcinoma in situ (DCIS), high nuclear grade, solid type.
- DCIS comprises less than 10% of biopsy tissue volume, and is associated with all three invasive tumor nodules.
- Mastectomy margins are free of tumor.
- Carcinoma is 3 cm from the inferior margin and is at least 6 cm from all other margins.
- Metastatic carcinoma in three of fifteen lymph nodes (3/15).
- Largest metastatic focus: 0.9 cm in diameter.
- Extranodal extension present.
- Positive lymph nodes are sentinel lymph nodes #2, #3, and #4

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Invasive ductal carcinoma, Nottingham grade 2-3.

Type and grade (in situ): DCIS, high-nuclear grade.

Primary tumor: pT1c(m).

Regional lymph nodes: pN1c.

Distant metastasis: Not applicable.

Stage: IIA.

Lymphovascular invasion: Indeterminate.

Margin status: Negative.

ICD-O-3

Carcinoma, infiltrating duct NOS
8500/3

Site (R) Breast NOS
C50.9

Q4 10/4/13

COMMENT: The three foci of invasive carcinoma have similar histologic features, although the tumor grade is somewhat variable in the largest tumor nodule, where there is a variable rate of mitosis, and nuclear pleomorphism ranging from intermediate to high-grade. The smaller tumor nodules contain high-grade malignant

Case #:

Printed:

Page 1

This report continues... (FINAL)

MR No. -

Acct No. -

Patient Name -

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

epithelial cells arranged in solid sheets with frequent mitoses, compatible with Nottingham grade 3. There is enough morphologic similarity between three nodules to suggest that they have a common origin. Intradepartmental consultation: [REDACTED] concurs with this impression.

Invasive Breast Cancer Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed.. and CAP Protocol (revised June 2012).

Previous pathology specimens:

Case #:

Printed:

Page 2

this report continues... (FINAL)

MR No. -

Patient Name -

[page 3 of 6]
Patient:

Case #:

SPECIMEN IDENTIFICATION

Procedure/specimen type:

Laterality:

Lymph node sampling:

Modified radical mastectomy.

Right.

Sentinel lymph node biopsies followed by lymph node dissection.

INVASIVE CARCINOMA TUMOR CHARACTERISTICS

Histologic type:

Tumor sites:

Tumor size:

Tumor focality:

Histologic grade (Nottingham Score):

Tubule formation:

Nuclear pleomorphism:

Mitotic rate:

Invasive ductal carcinoma (multifocal).

6:00-8:00.

Largest tumor nodule 1.5 cm.

Multifocal.

2-3 of 3.

3 of 3.

2-3 of 3.

2-3 of 3 (variable mitotic rate).

Lymphovascular invasion:

Macroscopic and microscopic extent of tumor:

Indeterminate.

No skin or chest wall invasion identified.

DUCTAL CARCINOMA IN SITU (DCIS):

Present in association with three invasive tumor nodules.

MARGINS

Invasive carcinoma:

Negative.

Ductal carcinoma in situ:

Negative.

LYMPH NODES

Total lymph nodes examined

Number of lymph nodes involved

Size of largest metastatic deposit:

Extranodal extension:

15.

3.

0.9 cm.

Present.

PATHOLOGIC STAGING:

Primary Tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

AJCC Stage:

pT1c(m).

pN1a.

Not applicable.

IIA.

ANCILLARY STUDIES:

Estrogen receptor:

Progesterone receptor:

HER2:

Performed by _____ on 2
previous biopsies (additional HER2 studies
pending, to be reported in an addendum).

85-96% positive cells, strong intensity.

0% positive cells.

Additional studies pending, to be reported in an
addendum.

Case #

Printed:

Page 3

This report continues... (FINAL)

MR No. .

Acct No. .

Patient Name -

[page 4 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Ki-67:

Variable, previously reported 7-69%.

Source of Specimen:

- A. Sentinel lymph node;#1-- right axillary
- B. Sentinel lymph node;#2-- right axillary
- C. Sentinel lymph node;#3-- right axillary
- D. Sentinel lymph node;#4-- right axillary
- E. Breast surgical:right
- F. Axillary nodes right

Clinical History/Operative Dx:

Right breast cancer.

Intraoperative Diagnosis:

- A. Sentinel node #1 - diagnosis: Negative for carcinoma.
- B. Sentinel node #2 - diagnosis: Rare atypical cells, suspicious for carcinoma. (Defer to permanents).
- D. Sentinel node #4 and - diagnosis: Positive for carcinoma

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Part A is designated as sentinel node #1 right axilla, touch prep. Initially received in the fresh state four frozen section/touch prep evaluation is a 1.0 x 0.8 x 0.6 cm piece of red-tan soft tissue. Examination reveals a 0.7 x 0.6 x 0.5 cm lymph node. The cut surfaces are fatty and rubbery, pink and tan. Two touch imprint slides are prepared for microscopic evaluation. The lymph node is entirely

Page 4

Case #:

This report continues... (FINAL)

Printed:

MR No.

Acct No.

Patient Name -

age 4 Doc# 1

[page 5 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

submitted for routine histology in A1 with a sentinel node protocol performed.

B. Part B is sentinel node #2. Initially received in the fresh state for touch prep/frozen section evaluation is a 1.5 x 1.2 x 1.0 cm yellow-tan portion of tissue. Examination reveals a 0.8 x 0.6 x 0.6 cm lymph node. Sectioning demonstrates a rubbery, pink and tan cut surfaces. Two touch imprint slides are submitted for microscopic evaluation. The lymph node is entirely submitted for routine histology in B1 with a sentinel node protocol performed.

C. Part C designated as sentinel node #3 right axillary. Received in formalin is a 1.5 x 1.5 x 0.7 cm fragment of fat. Examination reveals two possible apparent lymph nodes, 0.8 x 0.6 x 0.4 cm each. The lymph node is serially sectioned and entirely submitted for microscopic evaluation in C1 with a sentinel lymph node protocol performed.

D. Part D is designated as sentinel node #4 right axillary. Initially received in the fresh state for frozen section/touch imprint evaluation is a 1.5 x 1.2 x 1.0 cm yellow-green portion of fatty soft tissue. Examination reveals a 1.0 x 0.8 x 0.8 cm dense, pink-gray lymph node. Two touch imprint slides and a representative section is submitted for frozen section evaluation. The residual frozen tissue is submitted in D1 for permanent sections and the touch imprint aspect of the lymph node is submitted in D2 for permanent sections with a sentinel lymph node protocol performed.

E. Received fresh labeled "right breast." Sutures present for orientation purposes. A portion of tumor is submitted for

Laterality: Right.

Specimen: Mastectomy.

Size of mastectomy: (M-L x S-I x A-P): 23.5 x 19 x 5 cm.

Axillary tail: Not present.

Skin: 24 x 18 cm, pigmented skin. Nipple/areola: Yes, center of skin.

Specimen weight: 971 grams.

Ink code: Blue – superior-anterior, orange – inferior-anterior, black – deep

Slabs: Total # 11, M-I= 1, L-S= 11. Nipple in slab #6.

Time of resection:

Time placed into formalin:

Time out of formalin:

Lesion 1: Biopsy site present.

Size: 1.5 x 1.4 x 0.8 cm, stellate, gray-white, firm mass.

Location: 6:00. Involves slabs # 3-4.

Distance to nearest margin(s): 3 cm from inferior margin, 6 cm from deep margin.

Lesion #2: Biopsy site present.

Size: 0.8 x 0.5 x 0.5 cm.

Location: 7:00. Involves slabs #2-3.

Distance to nearest margin(s): 6 cm from inferior.

Case #:

Printed:

Page 5

This report continues... (FINAL)

MR No. -

Acct No. -

Patient Name -

[page 6 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Lesion #3: No biopsy site present.
Size: 0.6 x 0.6 x 0.5 cm.
Location: 7:00. Involves slabs #4.
Distance to nearest margin(s): 5 cm from inferior.

Non-lesional breast: Fibrofatty breast tissue.

Cassette summary:

E1) smallest 7:00 tumor, previously biopsied (portion of the small tumor submitted for

E2-E4) largest 6:00 lesion,
E5) central breast tissue,
E6-E7) lateral breast tissue,
E8) nipple/subareolar breast tissue,
E9) representative breast tissue,
E10-E11) fibrous tissue medial to largest tumor,
E12) representative medial breast tissue,
E13) mass #3, 7:00,
E14-E15) central posterior breast tissue.

F. Part F is which axillary nodes, right. Received in formalin is an 83 gram partially tattered portion of yellow-tan fatty soft tissue, 13.0 x 9.0 x 2.6 cm. Examination reveals eleven lymph nodes ranging from 0.2 cm to 1.9 x 1.4 x 1.2 cm in greatest dimension. The lymph nodes are entirely submitted for microscopic evaluation.

Cassette summary:

F1) four lymph nodes,
F2) four lymph nodes,
F3) one lymph node, bisected,
F4) one lymph node, bisected,
F5-F6) largest lymph node, serially sectioned.

Diagnostic Discrepancy		✓
U/PAA Discrepancy		✓
Case is (circled):		
Reviewer (initials):		

Microscopic Description:

A. - C. Immunohistochemical stain: CK OSCAR, showing focal metastatic carcinoma in specimens B and C.

D. Immunohistochemical stain: CK OSCAR, highlighting metastatic carcinoma. HER2 - results pending, to be reported in an addendum.

E. Immunohistochemical stain: HER2, to be reported in an addendum.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

Page 6

END OF REPORT (FINAL)

MR No. -

Acct No.

Patient Name -

Source: NCI Genomic Data Commons file 0101a550-8206-4187-8ee9-6bcbfb499b7e (TCGA-AC-A7VB.53881871-C36B-4622-BFC6-4DA3635D7B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).